Surgical pathology report (de-identified scan), TCGA case TCGA-85-8353, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8353-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

	Case ID	Gross Description	Microscopic Description

[page 2 of 4]
Diagnosis Details	Comments	Formatted Path Report
		LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 8 x 8 x 8 cm Histologic type: Squamous cell carcinoma Histologic grade: Poorly differentiated Tumor extent: Visceral pleura Other tumor nodules: Not specified Lymph nodes: 8/10 positive for metastasis (Intrathoracical 8/10) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- lower

[page 3 of 4]
	ID	Excision Date

[page 4 of 4]
Laterality

Right-lower

Source: NCI Genomic Data Commons file 135a84ac-bdbd-438e-9235-ecb9f89d206b (TCGA-85-8353.03371D1D-3D2A-4983-890B-EEC3CDB34D90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).